Somatic mutation profile of tumor specimen BA3453D (aliquot aq-BA3453D) from BEATAML1.0 case 2764, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.3 years (27,879 days).
Specimen BA3453D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f30b1df-7c61-4abd-9cd1-b85a628c1a5e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3224D (Solid Tissue Normal), aliquot aq-BA3224D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f95636ad-4871-4a1c-adfc-e8a050130971

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1504T>G p.S502A | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs121918458, CM022450, CM055504, COSV61005465, COSV61007751, COSV61015981; ClinVar: pathogenic; called by muse, mutect2, varscan2
